Somatic mutation profile of tumor specimen TCGA-BR-A4QL-01A (aliquot TCGA-BR-A4QL-01A-31D-A25D-08) from TCGA case TCGA-BR-A4QL, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 75.8 years (27,668 days).
Specimen TCGA-BR-A4QL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f921ea9a-ebb3-48e7-aa80-c03963ada103.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4QL-10A (Blood Derived Normal), aliquot TCGA-BR-A4QL-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4022f966-e073-41fe-ba2f-8ee707fdcb61

The open-access MAF lists 2,114 somatic variants for this specimen: 1,627 protein-altering or splice-affecting, 452 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,051, Silent 452, Frame Shift Del 386, Frame Shift Ins 76, Nonsense Mutation 59, In Frame Del 21, Splice Site 20, Intron 17, Splice Region 11, RNA 7, 3'Flank 4, 5'Flank 3.

Variants (750 of 2,114; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPL | c.1171del p.R391Vfs*12 | Frame Shift Del (DEL) | VAF 55/183 reads (30%) | catalogued as rs751404811, CM045926, CM138787; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 26/87 reads (30%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AXIN2 | c.1994del p.G665Afs*24 | Frame Shift Del (DEL) | VAF 27/71 reads (38%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- BARD1 | c.623del p.K208Rfs*4 | Frame Shift Del (DEL) | VAF 27/73 reads (37%) | catalogued as rs587780033; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CHD7 | c.2839C>T p.R947* | Nonsense Mutation (SNP) | VAF 9/55 reads (16%) | catalogued as rs200220845, CM066000, COSV71107204; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 28/87 reads (32%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- CYLD | c.2272C>T p.R758* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as rs121908388, CM001116, COSV100282806, COSV61092791; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- DCX | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587783541, CM131051, CM980524, COSV57565978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DVL1 | c.1637del p.P546Hfs*128 (on ENST00000378888 / NM_001330311.2; = p.P521Hfs*128 on NM_004421.3) | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs797044839, CD152686; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DYNC1H1 | c.6271C>T p.R2091W | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866242352, COSV64134352; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 55/128 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLNB | c.1592dup p.H532Tfs*9 | Frame Shift Ins (INS) | VAF 32/70 reads (46%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, varscan2
- GCK | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 91/243 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762263694, CM940823, COSV61752509; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HNF1B | c.1561del p.Q521Sfs*70 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | catalogued as rs764042837; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.303del p.S102Afs*28 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs797045661, CD160605; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LRP5 | c.4099G>A p.E1367K | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs28939709, CM043029, COSV53711219; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K4 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 47/141 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62254942, COSV62259088; called by muse, mutect2, varscan2
- MEN1 | c.1189del p.E397Sfs*53 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | catalogued as rs386134247, CD972315, CM994388, COSV99036887; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 62/166 reads (37%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NCSTN | c.17del p.G6Vfs*22 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs1266104510; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 29/61 reads (48%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- OCRL | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853260, CM981410, COSV63980092; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PALB2 | c.839del p.N280Tfs*8 | Frame Shift Del (DEL) | VAF 56/150 reads (37%) | catalogued as rs1555461597; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC17A5 | c.349del p.Y117Mfs*17 | Frame Shift Del (DEL) | VAF 71/224 reads (32%) | catalogued as rs772039085; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 15/92 reads (16%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A4GALT | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as rs1384790388, COSV50743973; called by muse, mutect2, varscan2
- AARS2 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as rs747514149, COSV55113269; called by muse, mutect2, varscan2
- AATK | c.3613C>T p.R1205C (on ENST00000326724 / NM_001080395.3; = p.R1102C on NM_004920.2) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs572926712, COSV58364022; called by muse, mutect2, varscan2
- ABCA1 | c.2569T>C p.Y857H | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); catalogued as COSV66063771; called by muse, mutect2, varscan2
- ABCA3 | c.4648C>T p.R1550W | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs781422468, CM085188, COSV57049489; called by muse, mutect2, varscan2
- ABCB4 | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.443); catalogued as COSV55931970; called by muse, mutect2, varscan2
- ABCC1 | c.2756C>A p.S919Y | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV60680309; called by muse, mutect2, varscan2
- ABCC5 | c.3287G>A p.R1096Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55587114; called by muse, varscan2
- ABCG1 | c.712A>G p.M238V | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV59200627; called by muse, mutect2, varscan2
- ABTB1 | c.1385A>G p.Q462R (on ENST00000232744 / NM_172027.3; = p.Q320R on NM_032548.3) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV51739959; called by muse, mutect2, varscan2
- AC005324.2 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); catalogued as rs1479639529; called by muse, mutect2, varscan2
- AC005324.2 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.053); catalogued as COSV60885635; called by muse, mutect2, varscan2
- ACAA2 | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.113); catalogued as COSV53269966; called by muse, mutect2, varscan2
- ACIN1 | c.1339del p.A447Lfs*19 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs879396950, COSV52972585; called by mutect2, varscan2
- ACOX3 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as rs116281866, COSV62710831; called by muse, mutect2, varscan2
- ACTL6A | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66998630; called by muse, mutect2, varscan2
- ACVR1B | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57774926; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 41/97 reads (42%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAD1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56641528; called by muse, mutect2, varscan2
- ADAM23 | c.2340del p.K781Rfs*14 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as rs767549806; called by mutect2, pindel, varscan2
- ADAM29 | c.2101del p.S701Vfs*4 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs34732497, COSV63661841; called by pindel, varscan2
- ADAMTS10 | c.2351A>G p.Q784R | Missense Mutation (SNP) | VAF 73/92 reads (79%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV54351977; called by muse, mutect2, varscan2
- ADAMTS14 | c.3552del p.L1187Cfs*23 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | catalogued as COSV100941680; called by mutect2, pindel, varscan2
- ADAMTS8 | c.1993G>A p.G665S | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776551880, COSV57291160; called by muse, mutect2, varscan2
- ADAMTSL4 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as rs372319782; called by muse, mutect2, varscan2
- ADCY10 | c.1597G>T p.A533S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV63238547; called by muse, mutect2, varscan2
- ADCY8 | c.3723G>T p.Q1241H | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV53896455, COSV53919410; called by muse, varscan2
- ADCY8 | c.2192G>T p.S731I | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV53896468; called by muse, mutect2, varscan2
- ADCYAP1 | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52485767, COSV52487327; called by muse, mutect2, varscan2
- ADGRG4 | c.2918T>C p.I973T | Missense Mutation (SNP) | VAF 91/233 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV54949420; called by muse, mutect2, varscan2
- ADGRV1 | c.9068G>T p.R3023M | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as rs1426031335, COSV67987618; ClinVar: uncertain significance; called by mutect2, varscan2
- ADGRV1 | c.16252G>A p.V5418M | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs776337063, COSV67978513; called by muse, mutect2, varscan2
- AEN | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756247681, COSV60428818; called by muse, mutect2, varscan2
- AFAP1L2 | c.337G>C p.A113P | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58412273; called by muse, mutect2, varscan2
- AGAP1 | c.2275G>A p.E759K (on ENST00000304032 / NM_001037131.3; = p.E706K on NM_014914.5) | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs759890571, COSV58317509; called by muse, mutect2, varscan2
- AGL | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV54048207; called by muse, mutect2, varscan2
- AGO1 | c.2276G>A p.R759Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64594675; called by muse, mutect2, varscan2
- AGO2 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as COSV55045075; called by muse, mutect2, varscan2
- AJAP1 | c.881T>C p.I294T | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs774959047, COSV65448920; called by muse, mutect2, varscan2
- AKAP14 | c.94T>G p.Y32D | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.979); catalogued as COSV57629260; called by muse, mutect2, varscan2
- AKAP6 | c.5687del p.N1896Mfs*17 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | catalogued as COSV99800479; called by mutect2, pindel, varscan2
- AKAP9 | c.7232A>G p.Q2411R (on ENST00000359028; = p.Q2387R on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as COSV62338716; called by muse, mutect2, varscan2
- AKAP9 | c.8641C>T p.H2881Y (on ENST00000359028; = p.H2857Y on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as rs766106000, COSV62338726; called by muse, mutect2, varscan2
- ALDH18A1 | c.1993C>T p.R665* | Nonsense Mutation (SNP) | VAF 114/269 reads (42%) | catalogued as rs751181507, COSV64662072; called by muse, mutect2, varscan2
- ALDH1L1 | c.1540G>A p.V514I | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs368202745, COSV99856718; called by muse, mutect2, varscan2
- ALDH2 | c.864del p.K289Rfs*122 | Frame Shift Del (DEL) | VAF 24/59 reads (41%) | catalogued as rs771889973, COSV55672572; called by mutect2, varscan2
- ALG11 | c.52del p.Y18Ifs*35 | Frame Shift Del (DEL) | VAF 25/72 reads (35%) | catalogued as COSV73000541; called by mutect2, pindel, varscan2
- ALG6 | c.658A>T p.K220* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as COSV54763209; called by muse, mutect2, varscan2
- ALKBH1 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs1386123998, COSV53173694; called by muse, mutect2, varscan2
- ALOX12B | c.1960G>A p.V654M | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV59870999; called by muse, mutect2, varscan2
- ALPG | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs542023570, COSV54964900; called by muse, mutect2, varscan2
- ALX1 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs774149369, COSV57491155; called by muse, mutect2, varscan2
- AMBRA1 | c.3581C>T p.T1194M (on ENST00000458649 / NM_001367468.1; = p.T1104M on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs762502501, COSV54048512; called by muse, mutect2, varscan2
- AMER2 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV63436079; called by muse, mutect2
- AMY2B | c.1135A>G p.N379D | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778631331, COSV63714038; called by muse, mutect2, varscan2
- AMY2B | c.1268A>G p.N423S | Missense Mutation (SNP) | VAF 96/307 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV100796182; called by muse, mutect2, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 29/118 reads (25%) | catalogued as rs34047276; called by mutect2, varscan2
- ANK1 | c.5518G>A p.A1840T | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs749120821, COSV55872811; called by muse, mutect2, varscan2
- ANKIB1 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs376898258, COSV56058565; called by muse, mutect2, varscan2
- ANKRD12 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50819177; called by muse, mutect2, varscan2
- ANKRD23 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs370284092; called by muse, mutect2, varscan2
- ANO10 | c.14T>C p.L5S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV52728437; called by muse, mutect2, varscan2
- ANO5 | c.1082A>T p.D361V | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); catalogued as COSV61082080; called by muse, mutect2, varscan2
- ANPEP | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201704361; called by muse, mutect2, varscan2
- ANXA10 | c.196-1G>A p.X66_splice | Splice Site (SNP) | VAF 18/50 reads (36%) | catalogued as COSV63738005; called by muse, mutect2
- AOC1 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs200294204, COSV62866837; called by muse, mutect2, varscan2
- AOC3 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV53824188; called by muse, mutect2, varscan2
- AOC3 | c.1807T>A p.Y603N | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53824191; called by muse, mutect2, varscan2
- AP2A2 | c.170del p.K57Sfs*24 | Frame Shift Del (DEL) | VAF 20/129 reads (16%) | catalogued as rs753029866; called by mutect2, varscan2
- AP3B1 | c.2791C>T p.H931Y | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV54876455; called by muse, mutect2, varscan2
- APLP1 | c.1895G>A p.R632H (on ENST00000221891 / NM_001024807.3; = p.R631H on NM_005166.4) | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV55701609; called by muse, mutect2, varscan2
- APOA1 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV52635266; called by muse, mutect2, varscan2
- ARFGEF2 | c.2439G>T p.E813D | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.087); catalogued as COSV64210454; called by muse, mutect2, varscan2
- ARHGAP26 | c.1643T>C p.M548T | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV50824282; called by muse, mutect2, varscan2
- ARHGAP39 | c.2849G>A p.W950* (on ENST00000276826 / NM_001308208.2; = p.W981* on NM_025251.2) | Nonsense Mutation (SNP) | VAF 23/73 reads (32%) | catalogued as COSV52766991; called by muse, mutect2, varscan2
- ARHGEF1 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV61526279; called by muse, mutect2, varscan2
- ARID1A | c.1803+2T>C p.X601_splice | Splice Site (SNP) | VAF 44/112 reads (39%) | catalogued as COSV61371879; called by muse, mutect2, varscan2
- ARMCX2 | c.1487T>C p.M496T | Missense Mutation (SNP) | VAF 87/191 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57529227; called by muse, mutect2, varscan2
- ARMCX2 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1259351624, COSV57529232; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.50del p.K17Rfs*21 | Frame Shift Del (DEL) | VAF 35/90 reads (39%) | catalogued as rs1290336606; called by mutect2, varscan2
- ARPC2 | c.560_562del p.E187del | In Frame Del (DEL) | VAF 55/123 reads (45%) | catalogued as rs1479878512; called by pindel, varscan2
- ARPP21 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51792179; called by muse, mutect2, varscan2
- ARRB1 | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63574344; called by muse, mutect2, varscan2
- ARSF | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 38/111 reads (34%) | catalogued as rs1006172488, COSV63838969; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs753865255; called by mutect2, varscan2
- ARSK | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs776266197, COSV66169215; called by muse, mutect2, varscan2
- ASAP3 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as rs765453970, COSV100369366, COSV60873017; called by muse, mutect2, varscan2
- ASB12 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs759856795, COSV62856022, COSV62856289; called by muse, mutect2, varscan2
- ASH1L | c.4554A>C p.R1518S | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.628); catalogued as rs754691861, COSV64205456, COSV64209204; called by muse, mutect2, varscan2
- ASIC4 | c.1159G>A p.E387K (on ENST00000347842 / NM_182847.3; = p.E406K on NM_018674.6) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs763537185, COSV61730950; called by muse, mutect2, varscan2
- ASXL2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 55/157 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV55453631; called by muse, mutect2, varscan2
- ATF2 | c.944T>A p.L315* | Nonsense Mutation (SNP) | VAF 48/148 reads (32%) | catalogued as COSV51367882; called by muse, mutect2, varscan2
- ATIC | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 26/60 reads (43%) | catalogued as rs556853914, COSV52691832; called by muse, mutect2, varscan2
- ATL1 | c.1111del p.M371Wfs*29 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | catalogued as rs1566733927; called by mutect2, pindel, varscan2
- ATN1 | c.964del p.A322Pfs*50 | Frame Shift Del (DEL) | VAF 38/120 reads (32%) | catalogued as COSV100755603; called by mutect2, pindel, varscan2
- ATOH1 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757448327, COSV60037408; called by muse, mutect2, varscan2
- ATP10A | c.3749C>T p.A1250V | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs146387652; called by muse, mutect2, varscan2
- ATP10B | c.2557G>A p.A853T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV59143818, COSV59146107; called by muse, mutect2, varscan2
- ATP1A2 | c.1133C>T p.T378I | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934002, CM041245, COSV63402307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B3 | c.2644G>A p.V882M | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs200009523, COSV54840367, COSV54845765; called by muse, mutect2, varscan2
- ATP4A | c.2162C>T p.A721V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.732); catalogued as rs145835787; called by muse, mutect2, varscan2
- ATP7B | c.3671G>A p.R1224Q | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as rs532177115, COSV54434699, COSV54435171; called by muse, mutect2, varscan2
- ATP8A2 | c.782T>C p.L261P | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54937078; called by muse, mutect2, varscan2
- ATP8A2 | c.1844A>C p.H615P | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV54937093, COSV54951351; called by muse, mutect2, varscan2
- ATP9B | c.2975C>T p.A992V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.691); catalogued as COSV56946532; called by muse, mutect2, varscan2
- ATXN2 | c.3140C>A p.P1047Q (on ENST00000550104; = p.P887Q on NM_002973.4) | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV66481267; called by muse, mutect2, varscan2
- ATXN7L1 | c.100C>A p.R34S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59491499; called by muse, mutect2, varscan2
- AVPR1A | c.196del p.V66Cfs*62 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | catalogued as COSV100146936; called by mutect2, pindel, varscan2
- AXL | c.1868T>C p.M623T (on ENST00000301178 / NM_021913.5; = p.M614T on NM_001699.6) | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs1568417786, COSV56563714; called by muse, mutect2, varscan2
- B4GALNT3 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs750727320, COSV56749712; called by muse, mutect2, varscan2
- BAG6 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs1398216799, COSV52987953; called by muse, mutect2, varscan2
- BAHD1 | c.300del p.S101Afs*107 | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | catalogued as COSV69084900; called by mutect2, pindel, varscan2
- BAIAP3 | c.2054G>A p.R685H | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.431); catalogued as rs749165160, COSV50103534; called by muse, mutect2, varscan2
- BCL11A | c.1087C>T p.R363C (on ENST00000335712 / NM_001365609.1; = p.R397C on NM_018014.4) | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59624433; called by muse, varscan2
- BCL6B | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); catalogued as COSV53426247; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 40/90 reads (44%) | catalogued as rs768244116; called by mutect2, varscan2
- BDNF | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs771341699, COSV59233173; called by muse, mutect2, varscan2
- BEND4 | c.642C>G p.H214Q | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV72468927; called by muse, mutect2, varscan2
- BHLHE22 | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs1236079178, COSV58861245; called by muse, mutect2
- BHLHE22 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV58861252; called by muse, mutect2, varscan2
- BHMT | c.594del p.G199Afs*8 | Frame Shift Del (DEL) | VAF 30/91 reads (33%) | catalogued as rs773277176; called by mutect2, pindel, varscan2
- BIRC6 | c.1274A>T p.E425V | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as COSV70195539; called by muse, mutect2, varscan2
- BLM | c.2423G>A p.R808H | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1399382807, COSV61921726; called by muse, mutect2, varscan2
- BLOC1S6 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as COSV55034955; called by muse, mutect2, varscan2
- BMP2K | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV58592006; called by muse, mutect2, varscan2
- BMPR1A | c.758G>A p.W253* | Nonsense Mutation (SNP) | VAF 29/63 reads (46%) | catalogued as COSV64405946; called by muse, mutect2, varscan2
- BNIP1 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs756656154, COSV51569939; called by muse, mutect2, varscan2
- BRD4 | c.2441G>A p.G814D | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.425); catalogued as COSV54582267; called by muse, mutect2
- BRF2 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV55102644; called by muse, mutect2, varscan2
- BRWD1 | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV60892691; called by muse, mutect2, varscan2
- BSN | c.9415C>T p.R3139C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.425); catalogued as rs769903799, COSV56513013, COSV99610109; called by muse, mutect2, varscan2
- C12orf71 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.056); catalogued as rs369942491; called by muse, mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | catalogued as rs750339990; called by mutect2, pindel, varscan2
- CAB39L | c.285del p.D96Mfs*2 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | catalogued as COSV61714509; called by mutect2, pindel, varscan2
- CACNA1A | c.3603del p.E1202Rfs*43 | Frame Shift Del (DEL) | VAF 52/88 reads (59%) | catalogued as rs747879307; called by mutect2, pindel, varscan2
- CACNA1B | c.393C>T p.D131= | Splice Region (SNP) | VAF 23/58 reads (40%) | catalogued as rs774589225, COSV53113802; called by muse, mutect2, varscan2
- CACNA1C | c.3386C>T p.T1129M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as rs374549078; called by muse, mutect2, varscan2
- CACNA1E | c.3526G>A p.V1176I | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.48); catalogued as rs1228218600, COSV62382262; called by muse, mutect2, varscan2
- CACNA1F | c.2303C>T p.T768I | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV59903031; called by muse, mutect2, varscan2
- CACNA1F | c.2087C>T p.T696M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV59903036; called by muse, mutect2, varscan2
- CACNA1H | c.6686G>A p.R2229K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV52352642; called by muse, mutect2, varscan2
- CACNA1I | c.2530G>A p.A844T | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV60801048; called by muse, mutect2, varscan2
- CACNA1S | c.2072C>T p.P691L | Missense Mutation (SNP) | VAF 122/296 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as COSV62936139; called by muse, mutect2, varscan2
- CACNA1S | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs753901380, COSV62941976; called by muse, mutect2, varscan2
- CACNB3 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.63); catalogued as rs747404713, COSV56397136; called by muse, mutect2, varscan2
- CAMK1G | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50520218; called by muse, mutect2, varscan2
- CAMKV | c.356A>G p.E119G | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56553979; called by muse, mutect2
- CAMSAP2 | c.3789del p.K1263Nfs*19 (on ENST00000236925 / NM_001297707.2; = p.K1252Nfs*19 on NM_203459.3) | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | catalogued as rs770273913; called by mutect2, varscan2
- CARD9 | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1319124870, COSV59996257; called by muse, mutect2
- CARMIL1 | c.3722C>T p.A1241V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV61513671; called by muse, mutect2, varscan2
- CARTPT | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.599); catalogued as rs1314552851, COSV57114729; called by muse, mutect2, varscan2
- CASC3 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 73/233 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs201645449, COSV52865976; called by muse, mutect2, varscan2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs770159446; called by mutect2, varscan2
- CASZ1 | c.4246C>T p.R1416W | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs772938935, COSV65456081; called by muse, mutect2, varscan2
- CBLL2 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1021989920, COSV60368379; called by muse, mutect2, varscan2
- CBLN3 | c.174dup p.P59Afs*25 | Frame Shift Ins (INS) | VAF 4/9 reads (44%) | catalogued as rs1385647942; called by mutect2, varscan2
- CCDC110 | c.1774del p.T592Hfs*5 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | catalogued as rs368765497; called by mutect2, pindel, varscan2
- CCDC114 | c.829C>A p.L277M | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.943); catalogued as COSV59555328; called by muse, mutect2
- CCDC120 | c.1372G>A p.G458S | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as rs974624326, COSV64480590; called by muse, mutect2, varscan2
- CCDC148 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs549719274, COSV51754362; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 19/42 reads (45%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC47 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56721779; called by muse, mutect2, varscan2
- CCDC50 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.069); catalogued as COSV66667169; called by muse, mutect2, varscan2
- CCDC60 | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV59540039; called by muse, mutect2, varscan2
- CCDC70 | c.173T>C p.M58T | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs758815285, COSV54429827; called by muse, mutect2, varscan2
- CCDC97 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs1259908553, COSV54189483; called by muse, mutect2, varscan2
- CCNB3 | c.980T>C p.F327S | Missense Mutation (SNP) | VAF 91/222 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as COSV52069930; called by muse, mutect2, varscan2
- CCNB3 | c.3941T>C p.M1314T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV52069935; called by muse, mutect2, varscan2
- CCNDBP1 | c.430C>A p.P144T | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55746332; called by muse, mutect2, varscan2
- CCNL2 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 52/128 reads (41%) | catalogued as rs749300030, COSV68766100; called by muse, mutect2, varscan2
- CCSER2 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs1159171678, COSV56501668, COSV99825567; called by muse, mutect2, varscan2
- CD163L1 | c.2264C>T p.S755L | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.541); catalogued as rs375236297; called by muse, mutect2, varscan2
- CD248 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.092); catalogued as rs955375139, COSV60935716; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 23/95 reads (24%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC42BPG | c.3366C>T p.N1122= | Splice Region (SNP) | VAF 12/35 reads (34%) | catalogued as rs142016620; called by muse, mutect2, varscan2
- CDC73 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | catalogued as COSV66464965; called by muse, mutect2, varscan2
- CDCA4 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs375561549; called by muse, mutect2, varscan2
- CDH3 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs199812197, COSV50554871; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH9 | c.1775A>C p.D592A | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV50252371; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3886G>A p.E1296K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs747687931, COSV62572096; called by muse, mutect2, varscan2
- CDK9 | c.1003A>G p.M335V | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV64723354; called by muse, mutect2, varscan2
- CDKN2D | c.275T>C p.V92A | Missense Mutation (SNP) | VAF 104/130 reads (80%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV57263557; called by muse, mutect2, varscan2
- CEACAM8 | c.743A>T p.Y248F | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.794); catalogued as COSV54990088; called by muse, mutect2, varscan2
- CELSR3 | c.7753G>A p.A2585T | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.685); catalogued as rs1209782879, COSV50839993; called by muse, mutect2, varscan2
- CEMIP | c.551G>A p.W184* | Nonsense Mutation (SNP) | VAF 8/170 reads (5%) | catalogued as COSV54988150; called by muse, mutect2
- CENPT | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764520926, COSV54648121; called by muse, mutect2, varscan2
- CEP135 | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 28/93 reads (30%) | catalogued as rs138291324; called by muse, mutect2, varscan2
- CEP170B | c.2350C>T p.R784W (on ENST00000453495; = p.R713W on NM_015005.3) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs755440595, COSV69023202; called by muse, mutect2, varscan2
- CEP250 | c.6608A>C p.E2203A | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV61168231; called by muse, mutect2, varscan2
- CEP350 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1011668966, COSV62485650; called by muse, mutect2
- CERK | c.1428del p.K477Rfs*74 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | catalogued as rs761362852; called by mutect2, pindel, varscan2
- CETN2 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs373398188, COSV64743201; called by muse, mutect2, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 30/77 reads (39%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP52 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141718755; called by muse, mutect2, varscan2
- CHD5 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs1435656050, COSV52407518; called by muse, mutect2, varscan2
- CHD6 | c.6473C>T p.A2158V | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV64688403; called by muse, mutect2, varscan2
- CHD7 | c.7472G>A p.R2491H | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.143); catalogued as rs528722099, COSV71107208; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD8 | c.1349G>A p.R450H (on ENST00000646647 / NM_001170629.2; = p.R171H on NM_020920.4) | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as rs774081833, COSV67869672; called by muse, mutect2, varscan2
- CHMP7 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as rs769951659, COSV57532204; called by muse, mutect2, varscan2
- CHRNB2 | c.758T>C p.I253T | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV63807702; called by muse, mutect2, varscan2
- CHST2 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58884710; called by muse, mutect2
- CHST4 | c.19del p.M7* | Frame Shift Del (DEL) | VAF 49/140 reads (35%) | catalogued as rs745406065; called by mutect2, pindel, varscan2
- CHTF18 | c.2789C>T p.A930V | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV50210154; called by muse, mutect2, varscan2
- CIBAR1 | c.53C>T p.T18I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV63896694; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | catalogued as rs752250702; called by mutect2, varscan2
- CLCN6 | c.2530-1G>C p.X844_splice | Splice Site (SNP) | VAF 45/118 reads (38%) | catalogued as COSV56737882; called by muse, mutect2, varscan2
- CLDN3 | c.163G>C p.V55L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV67777037; called by muse, mutect2, varscan2
- CLDND1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.513); catalogued as rs761957957, COSV57858154, COSV57858167; called by muse, mutect2, varscan2
- CLEC2D | c.567A>G p.I189M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as rs756873101, COSV51992528; called by muse, mutect2, varscan2
- CLIP2 | c.530C>T p.T177M | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1416219777, COSV56274445; called by muse, mutect2, varscan2
- CLK3 | c.460C>T p.R154* (on ENST00000395066 / NM_001130028.1; = p.R6* on NM_003992.4) | Nonsense Mutation (SNP) | VAF 69/166 reads (42%) | catalogued as rs755816350, COSV61411713; called by muse, mutect2, varscan2
- CLPTM1 | c.440A>G p.E147G | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.288); catalogued as COSV61610969; called by muse, mutect2, varscan2
- CLPTM1L | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs756950098, COSV57989345; called by muse, mutect2, varscan2
- CLRN1 | c.677T>C p.V226A | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55804628; called by muse, mutect2, varscan2
- CNGA4 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202065874, COSV66005056; called by muse, mutect2, varscan2
- CNGB1 | c.2924T>C p.L975P | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51897646; called by muse, mutect2, varscan2
- CNNM1 | c.1750C>T p.R584W | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs370860509, COSV63200211; called by muse, mutect2, varscan2
- CNOT6L | c.99del p.K33Nfs*7 (on ENST00000504123 / NM_001286790.2; = p.K28Nfs*7 on NM_144571.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 59/155 reads (38%) | catalogued as COSV99361610; called by mutect2, pindel, varscan2
- CNTN1 | c.1870T>C p.W624R | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301260149, COSV61636187; called by muse, mutect2, varscan2
- CNTN3 | c.2623T>C p.Y875H | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55163223; called by muse, mutect2
- CNTNAP1 | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs144243880; called by muse, mutect2, varscan2
- CNTNAP4 | c.2203T>C p.Y735H | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.059); catalogued as COSV56665003; called by muse, mutect2, varscan2
- CNTRL | c.5405del p.K1802Sfs*9 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs1217756472; called by mutect2, pindel
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 20/42 reads (48%) | catalogued as rs374805044; called by mutect2, varscan2
- COG2 | c.380del p.K127Rfs*5 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs1188081815, COSV100794718; called by mutect2, varscan2
- COL12A1 | c.8857G>A p.A2953T | Missense Mutation (SNP) | VAF 92/284 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.081); catalogued as COSV59389506; called by muse, mutect2, varscan2
- COL12A1 | c.6512T>C p.L2171S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59389512; called by muse, mutect2, varscan2
- COL12A1 | c.2147A>G p.E716G | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.573); catalogued as COSV59389522; called by muse, mutect2, varscan2
- COL1A1 | c.2539G>A p.A847T | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs369455732; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL20A1 | c.1336G>A p.V446M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775264398, COSV58911667; called by muse, mutect2, varscan2
- COL22A1 | c.2764G>A p.G922R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549307992, COSV57323217; called by muse, mutect2, varscan2
- COL26A1 | c.1042G>A p.V348M (on ENST00000313669 / NM_001278563.3; = p.V346M on NM_133457.4) | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs376558453, COSV100562201; called by muse, varscan2
- COL27A1 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.473); catalogued as rs771709770, COSV61921543; called by muse, mutect2, varscan2
- COL27A1 | c.5062C>T p.R1688W | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764138431, COSV61921549; called by muse, mutect2, varscan2
- COLEC11 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs896580554, COSV52591520; called by muse, mutect2, varscan2
- COLGALT1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs536730145, COSV53107527; called by muse, mutect2, varscan2
- COPA | c.1585C>T p.R529C | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767740500, COSV54097954; called by muse, mutect2, varscan2
- COPS6 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs370286743; called by muse, mutect2, varscan2
- COPS7A | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.241); catalogued as rs370260459; called by muse, mutect2, varscan2
- COQ8B | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV54685407; called by muse, mutect2, varscan2
- CPEB2 | c.1847A>G p.K616R | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52589329; called by muse, mutect2, varscan2
- CPOX | c.1276C>T p.R426* | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | catalogued as rs202148820, CM011767, COSV51637434; called by muse, mutect2, varscan2
- CPS1 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as CM114322, COSV51802092; called by muse, mutect2, varscan2
- CPSF1 | c.3767A>G p.Y1256C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs141624286, COSV58232189; called by muse, mutect2, varscan2
- CPZ | c.1016G>A p.R339H (on ENST00000360986 / NM_001014447.3; = p.R328H on NM_003652.3) | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.301); catalogued as rs368933993, COSV59921533; called by muse, mutect2
- CRACD | c.1829T>C p.L610P | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51715181; called by muse, mutect2, varscan2
- CRCT1 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 6/11 reads (55%) | PolyPhen probably damaging (0.997); catalogued as rs776655211, COSV57499890; called by muse, mutect2, varscan2
- CREBBP | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233360493, COSV52114262; called by muse, varscan2
- CRIM1 | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54859479; called by muse, mutect2, varscan2
- CROCC | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.197); catalogued as rs372750456; called by muse, mutect2, varscan2
- CRTAC1 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1306143159, COSV53997072; called by muse, mutect2, varscan2
- CRTC3 | c.1838C>T p.T613M | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs760894740, COSV51594300; called by muse, mutect2, varscan2
- CRYBB1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 52/68 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1400757152, COSV53232441; called by muse, mutect2, varscan2
- CRYBG2 | c.4873G>A p.E1625K | Missense Mutation (SNP) | VAF 111/251 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs750756396, COSV57483765; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as rs76607193; called by muse, mutect2, varscan2
- CSH1 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs760583471, COSV60241797, COSV60243135; called by muse, varscan2
- CSMD1 | c.4375C>A p.P1459T (on ENST00000520002; = p.P1458T on NM_033225.6) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59281958; called by muse, mutect2, varscan2
- CSMD1 | c.3977C>T p.T1326M (on ENST00000520002; = p.T1325M on NM_033225.6) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs763797476, COSV59281996, COSV59369648; called by muse, mutect2, varscan2
- CSMD1 | c.3023C>T p.T1008M (on ENST00000520002; = p.T1007M on NM_033225.6) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs147113316, COSV59282026; called by muse, mutect2, varscan2
- CSMD1 | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV68168191; called by muse, mutect2, varscan2
- CSMD3 | c.8017G>A p.V2673I (on ENST00000297405 / NM_001363185.1; = p.V2569I on NM_052900.3) | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs745950211, COSV52103433; called by muse, mutect2, varscan2
- CST6 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs1289170130, COSV56408998; called by muse, mutect2
- CTBP2 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 41/105 reads (39%) | catalogued as rs1554881282, COSV61468853; called by muse, mutect2, varscan2
- CTCF | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 75/260 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs762060506, COSV50461656; called by muse, mutect2, varscan2
- CTNNA1 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 39/92 reads (42%) | catalogued as rs758599826, COSV57069583; called by muse, mutect2, varscan2
- CTNNA1 | c.2213del p.N738Ifs*53 | Frame Shift Del (DEL) | VAF 23/83 reads (28%) | catalogued as COSV100242223; called by mutect2, pindel, varscan2
- CTPS1 | c.1187dup p.L396Ffs*13 | Frame Shift Ins (INS) | VAF 35/88 reads (40%) | catalogued as rs36007898; called by mutect2, pindel, varscan2
- CTSA | c.1362C>T p.G454= | Splice Region (SNP) | VAF 8/27 reads (30%) | catalogued as rs764678474, COSV51940615; called by muse, mutect2, varscan2
- CTSC | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as rs997358516, COSV57056047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL9 | c.902A>G p.E301G | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV52725243; called by muse, mutect2
- CYP19A1 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 34/89 reads (38%) | catalogued as rs72552260, CM004195, COSV53057103; called by muse, mutect2, varscan2
- CYP26A1 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV56417026; called by muse, mutect2, varscan2
- DAAM1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62834150; called by muse, mutect2, varscan2
- DAAM2 | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as rs773938955, COSV51302353, COSV99225354; called by muse, mutect2, varscan2
- DAB1 | c.1340C>T p.T447M (on ENST00000371231; = p.T414M on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773635680, COSV64690176; called by muse, mutect2, varscan2
- DAB2IP | c.307C>T p.R103C (on ENST00000408936; = p.R75C on NM_032552.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs772572009, COSV52254552; called by muse, varscan2
- DAGLB | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); catalogued as rs1562475946, COSV51702147; called by muse, mutect2, varscan2
- DCAF1 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 110/265 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.075); catalogued as COSV60040559; called by muse, mutect2, varscan2
- DCAF5 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV58458443, COSV58463564; called by muse, mutect2, varscan2
- DCC | c.2989A>T p.M997L | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV59084542; called by muse, mutect2, varscan2
- DCHS1 | c.3224T>C p.V1075A | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.981); catalogued as rs940621456, COSV55030544; called by muse, mutect2, varscan2
- DCP1B | c.1606G>A p.V536I | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs747504838, COSV54967141; called by muse, mutect2, varscan2
- DCST1 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757559044, COSV55056462; called by muse, mutect2, varscan2
- DCST2 | c.41del p.G14Efs*23 | Frame Shift Del (DEL) | VAF 26/75 reads (35%) | catalogued as rs752911803; called by mutect2, pindel, varscan2
- DCSTAMP | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as rs988143439, COSV52576079; called by muse, varscan2
- DCTN2 | c.599dup p.D201Rfs*2 (on ENST00000548249 / NM_001261413.2; = p.D206Rfs*2 on NM_006400.4) | Frame Shift Ins (INS) | VAF 22/58 reads (38%) | catalogued as rs745744034; called by mutect2, varscan2
- DCXR | c.358A>G p.R120G | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV60955983; called by muse, mutect2, varscan2
- DDX43 | c.1087A>T p.K363* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as COSV64836411; called by muse, mutect2, varscan2
- DDX54 | c.1969C>T p.R657W | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs746859443, COSV58371890; called by muse, mutect2, varscan2
- DDX54 | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV58371900; called by muse, mutect2
- DDX58 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.018); catalogued as rs139635230; called by muse, mutect2, varscan2
- DEFB118 | c.307G>T p.V103F | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.17); catalogued as rs548448570, COSV53619615, COSV53620730; called by muse, mutect2, varscan2
- DEFB125 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1568457505, COSV66703046; called by muse, mutect2, varscan2
- DEGS2 | c.646T>G p.S216A | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV59783370; called by muse, mutect2, varscan2
- DENND3 | c.1960A>G p.M654V | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52800851; called by muse, mutect2, varscan2
- DGKI | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs761583087, COSV55936470; called by muse, mutect2, varscan2
- DHRS7C | c.10A>G p.M4V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs762919426, COSV57649619; called by muse, mutect2, varscan2
- DHX29 | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs748073891, COSV52416538; called by muse, mutect2, varscan2
- DHX34 | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.147); catalogued as COSV100169245; called by muse, mutect2, varscan2
- DIAPH2 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.116); catalogued as COSV61260471; called by muse, mutect2, varscan2
- DIP2C | c.3871C>T p.R1291W | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1564560514, COSV55146049; called by muse, mutect2, varscan2
- DISP2 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 82/264 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV51116475; called by muse, mutect2, varscan2
- DISP2 | c.2831G>A p.R944H | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.401); catalogued as rs1045098882, COSV51116484; called by muse, mutect2, varscan2
- DLC1 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 75/332 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.425); catalogued as rs368389913, COSV99363842; called by muse, mutect2, varscan2
- DLG1 | c.2251C>T p.R751* (on ENST00000419354 / NM_001290983.1; = p.R773* on NM_004087.2) | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as rs1390220134, COSV58377912; called by muse, mutect2, varscan2
- DLG3 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52079912; called by muse, mutect2, varscan2
- DLG5 | c.5618C>T p.A1873V | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs753947317, COSV64946738; called by muse, mutect2
- DLX5 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV56031716; called by muse, mutect2, varscan2
- DNAH1 | c.4472C>T p.A1491V | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs369943421, COSV70226407; called by muse, mutect2, varscan2
- DNAH7 | c.3221del p.L1074Cfs*23 | Frame Shift Del (DEL) | VAF 24/64 reads (38%) | catalogued as rs763352877; called by mutect2, varscan2
- DNAJB6 | c.568T>A p.S190T | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV51094258; called by muse, mutect2
- DNAJC13 | c.1255G>A p.V419I | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs373430445; called by muse, mutect2, varscan2
- DNAJC5B | c.321C>A p.S107R | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV52535739; called by muse, mutect2, varscan2
- DOCK1 | c.2252G>A p.R751H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.641); catalogued as COSV54729863, COSV54743083; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 19/37 reads (51%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK7 | c.4965T>A p.D1655E (on ENST00000635253 / NM_001367561.1; = p.D1624E on NM_033407.3) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51995841; called by muse, mutect2, varscan2
- DOK6 | c.579G>A p.W193* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV101234907, COSV66926316; called by muse, mutect2
- DPP4 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as rs1355424702, COSV62105067; called by muse, mutect2, varscan2
- DRAXIN | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs149999195, COSV53841802; called by muse, mutect2, varscan2
- DRP2 | c.386T>A p.L129Q | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.881); catalogued as COSV65809245; called by muse, mutect2
- DTX1 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV57495649; called by muse, mutect2, varscan2
- DUSP10 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.103); catalogued as rs757592372, COSV60456569; called by muse, mutect2, varscan2
- DVL3 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV57454837; called by muse, mutect2, varscan2
- DYSF | c.3274C>T p.R1092C | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs758284713, COSV50268158; ClinVar: uncertain significance; called by muse, varscan2
- E2F8 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1212690643, COSV51461828; called by muse, mutect2, varscan2
- EAF2 | c.334dup p.T112Nfs*4 | Frame Shift Ins (INS) | VAF 39/88 reads (44%) | catalogued as rs746509911; called by mutect2, varscan2
- EBF3 | c.1148C>T p.A383V (on ENST00000355311 / NM_001375392.1; = p.A374V on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs546805685, COSV62471735; called by muse, mutect2, varscan2
- EDNRB | c.1147dup p.Y383Lfs*7 (on ENST00000377211 / NM_001201397.1; = p.Y293Lfs*7 on NM_000115.5) | Frame Shift Ins (INS) | VAF 26/64 reads (41%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, varscan2
- EEA1 | c.2043+2T>C p.X681_splice | Splice Site (SNP) | VAF 27/73 reads (37%) | catalogued as COSV59282606; called by muse, mutect2, varscan2
- EFCAB7 | c.1468G>T p.G490C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64313934; called by muse, mutect2, varscan2
- EFHD1 | c.636G>T p.E212D | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV51131857; called by muse, mutect2, varscan2
- EFNA4 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as rs200331554, COSV63018009; called by muse, mutect2, varscan2
- EGFLAM | c.1097del p.G366Afs*32 | Frame Shift Del (DEL) | VAF 15/60 reads (25%) | catalogued as rs773311790; called by mutect2, pindel, varscan2
- EGFR | c.1913C>T p.T638M | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs571064657, COSV51771306; called by muse, mutect2, varscan2
- EHBP1L1 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as rs781139980, COSV58571480; called by muse, mutect2, varscan2
- EHD2 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs780481751, COSV54406741; called by muse, mutect2, varscan2
- EHHADH | c.2100del p.K700Nfs*10 | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | catalogued as rs747455018; called by mutect2, pindel, varscan2
- EIF4G3 | c.2591C>T p.A864V | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as COSV51674001; called by muse, mutect2, varscan2
- EIF5 | c.359A>T p.N120I | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV53684701; called by muse, mutect2
- EIF5B | c.1360del p.I454Yfs*5 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as COSV99177625; called by mutect2, varscan2
- ELAVL3 | c.47del p.G16Afs*35 | Frame Shift Del (DEL) | VAF 14/19 reads (74%) | catalogued as rs751148694; called by mutect2, varscan2
- ELFN2 | c.2341C>T p.R781W | Missense Mutation (SNP) | VAF 66/84 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68743798; called by muse, varscan2
- ELL | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1302090596, COSV53211087; called by muse, mutect2, varscan2
- ELL2 | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.425); catalogued as rs757275862, COSV52981064; called by muse, mutect2, varscan2
- ELMO2 | c.1945G>A p.A649T | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs763315321, COSV51681322; called by muse, mutect2, varscan2
- ELOVL1 | c.47-1G>A p.X16_splice | Splice Site (SNP) | VAF 11/17 reads (65%) | catalogued as COSV60521624; called by muse, mutect2, varscan2
- EMILIN1 | c.151dup p.R51Pfs*23 | Frame Shift Ins (INS) | VAF 13/33 reads (39%) | catalogued as rs1445463863; called by mutect2, pindel, varscan2
- ENPP2 | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV50009992; called by muse, mutect2, varscan2
- ENPP6 | c.728T>C p.M243T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV57065794; called by muse, mutect2, varscan2
- ENTPD7 | c.1738A>G p.T580A | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65111934; called by muse, mutect2, varscan2
- EOMES | c.1414G>A p.V472I | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.269); catalogued as rs201822269; called by muse, mutect2, varscan2
- EP300 | c.4879C>T p.R1627W | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV54325405, COSV54343776; called by muse, mutect2
- EPAS1 | c.1421G>C p.S474T | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as rs1459319402, COSV55384152; called by muse, mutect2, varscan2
- EPHA8 | c.2275C>T p.R759* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV51262610; called by muse, mutect2, varscan2
- EPHB4 | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as rs773679415, COSV62267903; called by muse, mutect2, varscan2
- EPN3 | c.1108T>G p.S370A | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV52137565; called by muse, mutect2, varscan2
- EPRS1 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416932288, COSV100859558, COSV65097113; called by muse, mutect2, varscan2
- EPS8L2 | c.2137del p.E713Rfs*114 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as rs1564981057; called by mutect2, pindel, varscan2
- ERBB3 | c.706T>C p.S236P | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as COSV57246873; called by muse, mutect2, varscan2
- ERBB3 | c.1537G>T p.G513C | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57246888; called by muse, mutect2, varscan2
- ERN2 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as rs371169798; called by muse, mutect2, varscan2
- ESYT3 | c.2481del p.F827Lfs*7 | Frame Shift Del (DEL) | VAF 33/85 reads (39%) | catalogued as rs772672190; called by mutect2, pindel, varscan2
- ETV1 | c.414dup p.T139Hfs*24 | Frame Shift Ins (INS) | VAF 30/73 reads (41%) | catalogued as rs769886672; called by mutect2, varscan2
- EVC | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs767144263, COSV53829244; called by muse, mutect2, varscan2
- EVL | c.560del p.P187Hfs*41 (on ENST00000402714 / NM_001330221.2; = p.P189Hfs*41 on NM_016337.3) | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | catalogued as rs746606863; called by mutect2, varscan2
- EVX2 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.207); catalogued as rs1285501467, COSV57962449; called by muse, mutect2
- FAM102A | c.461C>T p.T154M (on ENST00000373095 / NM_001035254.3; = p.T12M on NM_203305.2) | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as rs767525718, COSV55947353; called by muse, mutect2, varscan2
- FAM110C | c.797G>A p.G266D | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs1412530671, COSV100566881, COSV59655660; called by muse, mutect2, varscan2
- FAM118A | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs777058813, COSV53416092; called by muse, mutect2, varscan2
- FAM120C | c.2339G>A p.R780Q | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs1403641809, COSV100069585; called by muse, mutect2, varscan2
- FAM155A | c.269A>G p.Q90R | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1479429932, COSV65549232; called by muse, varscan2
- FAM171B | c.1721T>C p.M574T | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV59000736; called by muse, mutect2, varscan2
- FAM181A | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372111603; called by muse, mutect2, varscan2
- FAM20A | c.1555C>T p.Q519* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV56835599; called by muse, mutect2, varscan2
- FAM234A | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.491); catalogued as rs754703794, COSV51451440; called by muse, mutect2, varscan2
- FAM47C | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs781884172, COSV63723626; called by muse, mutect2, varscan2
- FAM47C | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.999); catalogued as COSV63723639; called by muse, mutect2, varscan2
- FAM50B | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs771811466, COSV66654505; called by muse, mutect2, varscan2
- FAM83E | c.1411del p.R471Gfs*70 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | catalogued as rs754029394, COSV52374478; called by mutect2, pindel, varscan2
- FAM86B1 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs775301778, COSV58667758; called by muse, mutect2, varscan2
- FAN1 | c.22_24del p.P8del | In Frame Del (DEL) | VAF 44/119 reads (37%) | catalogued as rs767783867; called by pindel, varscan2
- FANCI | c.3139C>T p.R1047C (on ENST00000310775 / NM_001376911.1; = p.R987C on NM_018193.3) | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.246); catalogued as rs1429500240, COSV55522829; called by muse, mutect2, varscan2
- FANCM | c.161A>G p.D54G | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs1343552060, COSV53531204; called by muse, mutect2, varscan2
- FAR2 | c.1535C>T p.T512M | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs775428447, COSV51723267, COSV51723679; called by muse, mutect2, varscan2
- FASTKD3 | c.459A>G p.I153M | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as COSV52941670; called by muse, mutect2, varscan2
- FAT1 | c.6302G>A p.R2101H | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.983); catalogued as rs755378789, COSV71671936, COSV71675475; called by muse, mutect2, varscan2
- FAT3 | c.4268C>T p.A1423V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1470726107, COSV53075755; called by muse, mutect2, varscan2
- FAT3 | c.7628G>A p.R2543Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.074); catalogued as rs1234031232, COSV53075769; called by muse, mutect2, varscan2
- FBXL17 | c.1550A>C p.E517A | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as COSV62848183; called by muse, mutect2, varscan2
- FBXO33 | c.704T>A p.I235N | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV53233270; called by muse, mutect2, varscan2
- FBXO4 | c.1100T>C p.L367P | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55851229; called by muse, varscan2
- FBXO4 | c.1118G>A p.G373D | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55851246; called by muse, varscan2
- FBXO42 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV65044507; called by muse, mutect2, varscan2
- FBXO43 | c.1970T>C p.L657P | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV71053299; called by muse, mutect2, varscan2
- FBXO9 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV55054826; called by muse, mutect2, varscan2
- FCRLA | c.943C>T p.P315S (on ENST00000367959; = p.P292S on NM_032738.4) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV52684266; called by muse, mutect2, varscan2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs747094222, COSV67548414; called by mutect2, pindel, varscan2
- FERMT2 | c.455del p.K152Rfs*4 | Frame Shift Del (DEL) | VAF 42/104 reads (40%) | catalogued as rs766229731; called by mutect2, varscan2
- FERMT3 | c.1931G>A p.R644Q (on ENST00000279227 / NM_178443.3; = p.R640Q on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs371563698, COSV99655720; called by muse, mutect2, varscan2
- FFAR4 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs567274570, COSV65178446, COSV65178781; called by muse, mutect2, varscan2
- FGD3 | c.421del p.Q141Rfs*33 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as rs1214182725; called by mutect2, pindel, varscan2
- FGD5 | c.932C>T p.T311I | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1448630696, COSV53237318; called by muse, mutect2, varscan2
- FGF8 | c.411+2T>C p.X137_splice (on ENST00000344255 / NM_033164.4; = p.X119_splice on NM_006119.6) | Splice Site (SNP) | VAF 25/69 reads (36%) | catalogued as COSV60142176; called by muse, mutect2, varscan2
- FGGY | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.21); catalogued as rs778888699, COSV100363762, COSV58037805; called by muse, mutect2, varscan2
- FILIP1L | c.2247dup p.L750Tfs*16 (on ENST00000354552 / NM_182909.3; = p.L510Tfs*16 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 50/134 reads (37%) | catalogued as rs1433753279; called by mutect2, varscan2
- FLG | c.4192A>C p.S1398R | Missense Mutation (SNP) | VAF 167/406 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as COSV64236563; called by muse, mutect2, varscan2
- FLG | c.2023G>T p.D675Y | Missense Mutation (SNP) | VAF 167/438 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs140188504, COSV64247847; called by muse, mutect2, varscan2
- FLNA | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as rs782539251, COSV61037548, COSV61050469; ClinVar: likely benign; called by muse, mutect2, varscan2
- FLNC | c.4141G>A p.G1381R | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766513255, COSV57950192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLOT2 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.119); catalogued as rs775401852, COSV101204754, COSV67528810; called by muse, mutect2, varscan2
- FN1 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552465703, COSV60546579; called by muse, mutect2, varscan2
- FNDC3A | c.3343C>T p.R1115C (on ENST00000492622 / NM_001079673.2; = p.R1059C on NM_014923.5) | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV68132284; called by muse, mutect2, varscan2
- FNDC4 | c.30del p.S11Afs*17 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs771665646, COSV99253963; called by mutect2, varscan2
- FOXD4L5 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.096); catalogued as rs1312738388, COSV66240756; called by muse, mutect2, varscan2
- FOXF1 | c.461T>C p.M154T | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs1205426218, COSV52284976; called by muse, mutect2, varscan2
- FOXO3 | c.1424C>T p.T475I | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV100669558; called by muse, mutect2, varscan2
- FRAS1 | c.3305C>T p.T1102I | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.071); catalogued as COSV53589271; called by muse, mutect2, varscan2
- FRMPD1 | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.106); catalogued as COSV100899622, COSV66699159; called by muse, mutect2, varscan2
- FSIP2 | c.20138del p.L6713Cfs*3 | Frame Shift Del (DEL) | VAF 34/107 reads (32%) | catalogued as COSV58085601; called by mutect2, pindel, varscan2
- FSTL5 | c.471T>G p.N157K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV60181672; called by muse, mutect2, varscan2
- FTSJ3 | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs763978409, COSV63789307; called by muse, mutect2, varscan2
- FUT7 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866808818, COSV55797456; called by muse, mutect2, varscan2
- FZD10 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV57476227; called by muse, mutect2
- FZD2 | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59528099; called by muse, mutect2, varscan2
- FZD3 | c.1533del p.H512Mfs*8 | Frame Shift Del (DEL) | VAF 37/131 reads (28%) | catalogued as rs1563404339; called by mutect2, pindel, varscan2
- FZD8 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65967500; called by muse, mutect2, varscan2
- GABPA | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61395333; called by muse, mutect2, varscan2
- GAD2 | c.1236G>T p.E412D | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV104387273, COSV52150697; called by muse, mutect2, varscan2
- GALNT16 | c.956del p.G319Efs*83 | Frame Shift Del (DEL) | VAF 28/86 reads (33%) | catalogued as rs763094427; called by mutect2, pindel, varscan2
- GALNTL6 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757975655, COSV72489350; called by muse, mutect2, varscan2
- GALNTL6 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.592); catalogued as COSV72489352; called by muse, mutect2, varscan2
- GALR2 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV57161560, COSV57164836; called by muse, mutect2, varscan2
- GART | c.2420del p.K807Rfs*7 | Frame Shift Del (DEL) | VAF 24/49 reads (49%) | catalogued as rs758551787; called by mutect2, varscan2
- GATA2 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.676); catalogued as rs769473824, COSV62003090; called by muse, mutect2, varscan2
- GBF1 | c.2863G>A p.A955T (on ENST00000369983 / NM_001377137.1; = p.A954T on NM_004193.3) | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.469); catalogued as COSV64142801; called by muse, mutect2, varscan2
- GCDH | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.582); catalogued as COSV53365484; called by muse, mutect2, varscan2
- GCN1 | c.6019G>A p.V2007M | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs536175743, COSV56103812, COSV56110191; called by muse, mutect2, varscan2
- GCNT3 | c.847_849del p.K283del | In Frame Del (DEL) | VAF 73/195 reads (37%) | catalogued as rs777839068; called by pindel, varscan2
- GDF15 | c.279G>A p.V93= | Splice Region (SNP) | VAF 17/49 reads (35%) | catalogued as COSV53250451; called by muse, mutect2, varscan2
- GGA3 | c.526A>G p.K176E (on ENST00000537686 / NM_138619.4; = p.K143E on NM_014001.5) | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV55455318; called by muse, mutect2, varscan2
- GHRHR | c.638C>T p.T213I | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.248); catalogued as COSV58195561; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs763147690; called by mutect2, varscan2
- GIMAP8 | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 28/70 reads (40%) | catalogued as rs746795576; called by mutect2, varscan2
- GJA5 | c.795del p.D266Tfs*118 | Frame Shift Del (DEL) | VAF 40/122 reads (33%) | catalogued as COSV54783230, COSV54783479; called by mutect2, pindel, varscan2
- GLI3 | c.2819C>T p.P940L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1285586325, COSV67885272; called by muse, mutect2, varscan2
- GLO1 | c.158T>A p.L53H | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64905001; called by muse, mutect2, varscan2
- GLOD5 | c.275A>G p.K92R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV57488777; called by muse, mutect2, varscan2
- GLUD2 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770086797, COSV60151186; called by muse, mutect2, varscan2
- GLYR1 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as COSV58925571; called by muse, mutect2, varscan2
- GMCL1 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.682); catalogued as rs536022280, COSV57000463; called by muse, mutect2, varscan2
- GNAS | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as CM013736, COSV55671184; called by muse, mutect2, varscan2
- GNAZ | c.612dup p.Q205Afs*35 | Frame Shift Ins (INS) | VAF 51/139 reads (37%) | catalogued as rs752075537; called by mutect2, varscan2
- GOLGA6A | c.856C>A p.P286T | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs751163856, COSV51804080; called by muse, mutect2, varscan2
- GPKOW | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs372379511, COSV50242086; called by muse, mutect2, varscan2
- GPNMB | c.922A>G p.T308A | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV51696880; called by muse, mutect2, varscan2
- GPR119 | c.957G>T p.R319S | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.188); catalogued as COSV52274905; called by muse, mutect2, varscan2
- GPR132 | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766876423, COSV61677545; called by muse, mutect2, varscan2
- GPR139 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV58501653; called by muse, mutect2, varscan2
- GPR15 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV52520016; called by muse, mutect2, varscan2
- GPR182 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs760555632, COSV100267656, COSV55625456, COSV55625815; called by muse, mutect2, varscan2
- GPR37L1 | c.706C>A p.L236M | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.439); catalogued as COSV66161897; called by muse, mutect2
- GPR50 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 87/174 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs372169533, COSV54436908; called by muse, mutect2, varscan2
- GPR61 | c.1135_1137del p.E379del | In Frame Del (DEL) | VAF 25/58 reads (43%) | catalogued as rs764745754; called by pindel, varscan2
- GPR78 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs368485565; called by muse, mutect2, varscan2
- GPRIN1 | c.2993G>T p.R998L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV56134676; called by muse, mutect2, varscan2
- GRB2 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 96/246 reads (39%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs767371260, COSV57303449; called by muse, mutect2, varscan2
- GRHL2 | c.1862C>T p.T621M | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as rs748576840, COSV52544558; called by muse, mutect2, varscan2
- GRIN2A | c.1231C>A p.L411M | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58020314; called by muse, mutect2, varscan2
- GRIN2B | c.2698C>T p.R900C | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1452515828, COSV74204785, COSV74207615; called by muse, mutect2, varscan2
- GRIN2D | c.3371C>T p.A1124V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.082); catalogued as rs1231092898, COSV53517724; called by muse, mutect2, varscan2
- GRM3 | c.2273C>T p.T758M | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs141671463; called by muse, mutect2, varscan2
- GRM4 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs764201799, COSV65210553; called by muse, mutect2, varscan2
- GRM5 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs202165348; called by muse, mutect2, varscan2
- GTDC1 | c.492C>A p.Y164* | Nonsense Mutation (SNP) | VAF 29/86 reads (34%) | catalogued as COSV53988334; called by muse, mutect2, varscan2
- GTF3C1 | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55173602; called by muse, mutect2, varscan2
- GTF3C3 | c.2174T>C p.L725S | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV55830938; called by muse, mutect2, varscan2
- GTF3C4 | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs778778757, COSV64644949; called by muse, mutect2, varscan2
- H1-6 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs142806773; called by muse, varscan2
- H1-6 | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as rs1272603620, COSV58089962; called by muse, varscan2
- HACD1 | c.618del p.F206Lfs*23 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as rs1564504589; called by mutect2, pindel, varscan2
- HAUS5 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as rs760065079, COSV52546558; called by muse, mutect2, varscan2
- HAUS6 | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV65839499; called by muse, mutect2, varscan2
- HCFC1 | c.4217C>T p.A1406V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs782239008, COSV60069400, COSV60079338; called by muse, mutect2, varscan2
- HDAC11 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as rs750078602, COSV55472403; called by muse, varscan2
- HDAC4 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs115644432, COSV100612592, COSV61859368; called by muse, mutect2, varscan2
- HDAC6 | c.2264C>T p.S755L | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV61927482; called by muse, mutect2, varscan2
- HDAC9 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs780726735, COSV67766859, COSV67772252; called by muse, varscan2
- HDLBP | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.919); catalogued as rs1289991895, COSV60492038; called by muse, mutect2, varscan2
- HEATR4 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs528517201, COSV58569867; called by muse, mutect2, varscan2
- HECTD2 | c.1144del p.I382Sfs*11 | Frame Shift Del (DEL) | VAF 45/120 reads (38%) | catalogued as rs57105282; called by mutect2, varscan2
- HECW1 | c.2668C>T p.R890* | Nonsense Mutation (SNP) | VAF 25/85 reads (29%) | catalogued as rs1563011701, COSV101222992, COSV67821831; called by muse, mutect2, varscan2
- HERC2 | c.8399G>A p.R2800H | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs368463146; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HIP1R | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs757099141, COSV53439291; called by muse, mutect2, varscan2
- HIPK4 | c.1243C>T p.R415* | Nonsense Mutation (SNP) | VAF 37/112 reads (33%) | catalogued as rs1555799118, COSV52519079; called by muse, mutect2, varscan2
- HIRA | c.2294G>A p.R765H | Missense Mutation (SNP) | VAF 89/241 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1556012805, COSV54272092; called by muse, mutect2, varscan2
- HIVEP1 | c.93del p.E32Kfs*17 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | catalogued as rs1561928340; called by mutect2, pindel, varscan2
- HMGB3 | c.269C>A p.P90H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV57485441; called by muse, mutect2, varscan2
- HMGCS2 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1064797117, COSV65567142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 32/71 reads (45%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPK | c.1298G>T p.R433L | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV61088231, COSV61089679; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 45/112 reads (40%) | catalogued as COSV57131171; called by muse, mutect2, varscan2
- HOOK1 | c.1089del p.A364Qfs*8 | Frame Shift Del (DEL) | VAF 28/105 reads (27%) | catalogued as COSV64619270; called by mutect2, pindel, varscan2
- HOXB6 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402121100, COSV53312128; called by muse, mutect2, varscan2
- HOXC13 | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746424242, COSV54498017; called by muse, mutect2, varscan2
- HOXD1 | c.635G>T p.R212M | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58923011; called by muse, mutect2, varscan2
- HOXD3 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1380499689, COSV50879069; called by muse, mutect2, varscan2
- HOXD4 | c.476C>T p.T159M | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751590168, COSV60459263, COSV60459298; called by muse, mutect2, varscan2
- HP1BP3 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56561289; called by muse, mutect2, varscan2
- HPD | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs140596268, COSV56640979; called by muse, mutect2, varscan2
- HR | c.2945G>A p.R982H | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs200243478; called by muse, mutect2, varscan2
- HSH2D | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs778471454, COSV53737066; called by muse, mutect2, varscan2
- HTR5A | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769172803, COSV55280454; called by muse, mutect2, varscan2
- HUWE1 | c.794A>G p.H265R | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV53334728; called by muse, mutect2, varscan2
- IARS2 | c.2351G>C p.R784P | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56957576; called by muse, mutect2, varscan2
- ICE2 | c.1899dup p.P634Tfs*7 | Frame Shift Ins (INS) | VAF 36/76 reads (47%) | catalogued as rs773511663; called by mutect2, varscan2
- IFI44L | c.1019A>G p.K340R | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.171); catalogued as COSV60726650; called by muse, mutect2, varscan2
- IFNLR1 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs146955345; called by muse, mutect2, varscan2
- IGF1R | c.3755A>G p.N1252S | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as rs1178294655, COSV51270092; called by muse, mutect2, varscan2
- IGF2R | c.1420_1422del p.L474del | In Frame Del (DEL) | VAF 46/139 reads (33%) | catalogued as rs1562353262; called by pindel, varscan2
- IGFALS | c.1169G>A p.S390N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51904626; called by muse, mutect2, varscan2
- IGFBPL1 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as COSV66617763; called by muse, mutect2, varscan2
- IGHV3-72 | c.74A>C p.E25A | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV101455359; called by muse, mutect2, varscan2
- IGLV1-44 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 110/147 reads (75%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs746009829; called by muse, mutect2, varscan2
- IGSF10 | c.7795G>A p.D2599N | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs201661662, COSV56368542; called by muse, mutect2, varscan2
- IGSF10 | c.3478G>A p.A1160T | Missense Mutation (SNP) | VAF 130/352 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs553213263, COSV56781590; called by muse, mutect2, varscan2
- IGSF3 | c.1214T>C p.L405P | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as COSV59585900; called by muse, varscan2
- IKBKE | c.1042del p.R348Dfs*32 | Frame Shift Del (DEL) | VAF 42/152 reads (28%) | catalogued as COSV65625022; called by mutect2, varscan2
- IL15RA | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.911); catalogued as rs371140892; called by muse, mutect2, varscan2
- IL16 | c.3276dup p.L1093Tfs*10 (on ENST00000302987 / NM_172217.5; = p.L392Tfs*10 on NM_004513.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 23/77 reads (30%) | catalogued as rs777448128; called by mutect2, varscan2
- IL1R2 | c.793G>A p.G265S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.638); catalogued as rs369088604, COSV60205391; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 30/90 reads (33%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- INO80D | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68958099; called by muse, mutect2
- INSIG1 | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769646258, COSV60919719; called by muse, mutect2, varscan2
- INSR | c.2327C>T p.T776M | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.768); catalogued as rs377048253; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INTS12 | c.41del p.L14* | Frame Shift Del (DEL) | VAF 55/186 reads (30%) | catalogued as COSV60863912; called by mutect2, pindel, varscan2
- INTS8 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs749115981, COSV58248594; called by muse, mutect2, varscan2
- IQCD | c.200C>T p.T67I | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV55320217; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1033G>T p.G345* (on ENST00000485419 / NM_001197113.1; = p.G269* on NM_014575.3) | Nonsense Mutation (SNP) | VAF 54/145 reads (37%) | catalogued as COSV61838864; called by muse, varscan2
- IQCN | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs970628103, COSV66572415; called by muse, mutect2
- IQSEC2 | c.2089G>A p.E697K (on ENST00000642864 / NM_001111125.3; = p.E492K on NM_015075.2) | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV64723548; called by muse, mutect2, varscan2
- IRAK2 | c.1225C>A p.L409I | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV56528710, COSV56534251; called by muse, mutect2, varscan2
- IRGC | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV54982842; called by muse, mutect2, varscan2
- IRS1 | c.3185del p.G1062Afs*8 | Frame Shift Del (DEL) | VAF 28/70 reads (40%) | catalogued as COSV59339024; called by mutect2, pindel, varscan2
- IRX1 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.146); catalogued as COSV57358735; called by muse, mutect2
- ISLR | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as COSV51432962; called by muse, mutect2, varscan2
- ITGA2 | c.572T>A p.V191E | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56856378, COSV56857126; called by muse, mutect2, varscan2
- ITGAE | c.2038G>A p.V680I | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.426); catalogued as COSV53989205; called by muse, mutect2, varscan2
- ITGAM | c.1591G>A p.V531I (on ENST00000648685 / NM_001145808.2; = p.V530I on NM_000632.4) | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.096); catalogued as COSV54934001; called by muse, mutect2, varscan2
- ITPR3 | c.2957G>A p.R986H | Missense Mutation (SNP) | VAF 9/239 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs868764253, COSV65408733, COSV65411666; called by muse, mutect2
- ITPR3 | c.5566G>A p.E1856K | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1470806540, COSV65405691; called by muse, mutect2, varscan2
- IZUMO2 | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV53229188; called by muse, mutect2, varscan2
- JADE2 | c.1856C>T p.T619M | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.849); catalogued as rs373153187; called by muse, mutect2, varscan2
- JAG1 | c.1504T>C p.C502R | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54753429; called by muse, mutect2, varscan2
- JAK3 | c.1580T>G p.L527R | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV71685523, COSV71685894; called by muse, mutect2, varscan2
- JAKMIP1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774030137, COSV51522294; called by muse, mutect2, varscan2
- JCAD | c.3772C>T p.R1258C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771848914, COSV64757946; called by muse, mutect2, varscan2
- JMJD1C | c.3869A>G p.H1290R | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1318617288, COSV59512732, COSV59513881; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JRK | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs781926968, COSV70629528; called by muse, mutect2, varscan2
- KAT6A | c.3528T>A p.S1176R | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV55902638; called by muse, mutect2, varscan2
- KAT6A | c.428T>G p.F143C | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs774222350, COSV55902645; called by muse, mutect2, varscan2
- KAT8 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV54895077; called by muse, mutect2, varscan2
- KBTBD8 | c.223T>C p.F75L | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV55126671; called by muse, mutect2, varscan2
- KCNA3 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63900926; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 44/167 reads (26%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNC3 | c.1564C>A p.L522M | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65386662; called by muse, mutect2, varscan2
- KCNG2 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs1345182001, COSV60266685; called by muse, mutect2
- KCNH3 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301009027, COSV57789567; called by muse, mutect2, varscan2
- KCNH4 | c.642del p.S215Lfs*62 | Frame Shift Del (DEL) | VAF 65/196 reads (33%) | catalogued as COSV99236896; called by mutect2, pindel, varscan2
- KCNJ16 | c.899T>A p.V300D | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV52250766; called by muse, mutect2, varscan2
- KCNJ4 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 167/427 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs765921539, COSV57856109; called by muse, mutect2, varscan2
- KCNJ6 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752712749, COSV55709503; called by muse, mutect2, varscan2
- KCNK17 | c.743G>T p.W248L | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237370466, COSV64684772; called by muse, mutect2, varscan2
- KCNMA1 | c.2306del p.K769Sfs*17 (on ENST00000286628 / NM_001161352.2; = p.K711Sfs*17 on NM_002247.4) | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | catalogued as rs771351714; called by mutect2, varscan2
- KCNN1 | c.808A>G p.T270A | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.08); catalogued as COSV55836962, COSV55837615, COSV55838227; called by muse, mutect2, varscan2
- KCNS3 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV58405291, COSV58405735; called by muse, mutect2, varscan2
- KCNU1 | c.1198C>G p.L400V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101298861, COSV67753095; called by muse, mutect2, varscan2
- KCNU1 | c.3094C>A p.L1032I | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV67753103, COSV67758075; called by muse, mutect2, varscan2
- KCNV1 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52084642; called by muse, mutect2, varscan2
- KCTD1 | c.530A>G p.N177S | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV58683542; called by muse, mutect2, varscan2
- KDM3A | c.191G>A p.C64Y | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.96); PolyPhen benign (0.005); catalogued as COSV57217963; called by muse, mutect2, varscan2
- KHDRBS2 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); catalogued as COSV55427246; called by muse, mutect2, varscan2
- KIAA1522 | c.1657A>T p.K553* (on ENST00000373480 / NM_001198972.2; = p.K612* on NM_020888.3) | Nonsense Mutation (SNP) | VAF 41/94 reads (44%) | catalogued as COSV53862345; called by muse, mutect2, varscan2
- KIAA1586 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV66056137; called by muse, mutect2, varscan2
- KIF1A | c.4864G>A p.V1622M (on ENST00000320389 / NM_001379639.1; = p.V1614M on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs766569322, COSV57482719; called by muse, mutect2, varscan2
- KIF2C | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs766564343, COSV64763878; called by muse, mutect2, varscan2
- KIRREL2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.685); catalogued as rs939777968, COSV52874329; called by muse, mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 58/148 reads (39%) | catalogued as COSV54711577; called by mutect2, pindel, varscan2
- KLHDC9 | c.387del p.A130Pfs*37 | Frame Shift Del (DEL) | VAF 4/8 reads (50%) | catalogued as rs761803466; called by mutect2, varscan2
- KLHL13 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53244693; called by muse, mutect2
- KLHL26 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250871209, COSV56316189; called by muse, mutect2, varscan2
- KLK10 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59397300; called by muse, mutect2, varscan2
- KMT2A | c.5291G>A p.R1764H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1555043444, COSV63282001; called by muse, mutect2, varscan2
- KMT2C | c.7106A>G p.N2369S | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV51290835; called by muse, mutect2, varscan2
- KMT5B | c.1157A>G p.Q386R | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV58563713; called by muse, mutect2, varscan2
- KNSTRN | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 36/103 reads (35%) | catalogued as rs369930942; called by muse, mutect2, varscan2
- KPNA2 | c.1201G>A p.V401M | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as rs782484137, COSV57856850; called by muse, mutect2
- KPNA3 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55503251; called by muse, mutect2, varscan2
- KRT17 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs759193608, COSV60859937; called by muse, mutect2, varscan2
- KRT27 | c.220G>T p.G74W | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV56970742, COSV56971798; called by muse, mutect2, varscan2
- KRT31 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs372409338; called by muse, mutect2, varscan2
- KRT39 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs750423441, COSV100842290, COSV62916833; called by muse, mutect2
- KRT4 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 96/203 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs747520287, COSV53405677, COSV53409222; called by muse, mutect2, varscan2
- KRT6B | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99360458; called by muse, mutect2, varscan2
- KRT73 | c.1390G>A p.G464R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as rs757577717, COSV59837880; called by muse, mutect2, varscan2
- KRT86 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs552266351, COSV53291503; called by muse, mutect2, varscan2
- KRTAP10-10 | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 143/364 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59951846, COSV59982734; called by muse, mutect2, varscan2
- KRTAP5-10 | c.398del p.G133Afs*84 | Frame Shift Del (DEL) | VAF 76/214 reads (36%) | catalogued as COSV100924168; called by mutect2, pindel, varscan2
- L1CAM | c.2500C>T p.R834W | Missense Mutation (SNP) | VAF 105/268 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs782716607, COSV62826807; called by muse, mutect2, varscan2
- LAMA1 | c.8329T>G p.F2777V | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV67532119; called by muse, mutect2, varscan2
- LAMA1 | c.7901C>T p.T2634M | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.522); catalogued as rs562948482, COSV67532123; called by muse, mutect2, varscan2
- LAMA5 | c.9504G>A p.P3168= | Splice Region (SNP) | VAF 6/11 reads (55%) | catalogued as rs759512310, COSV53352978; called by muse, mutect2, varscan2
- LAMB1 | c.3317T>C p.M1106T | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as COSV55961586; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 35/101 reads (35%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LCT | c.5337T>G p.A1779= | Splice Region (SNP) | VAF 22/87 reads (25%) | catalogued as COSV51544156; called by muse, mutect2, varscan2
- LGI3 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs143158388; called by muse, mutect2, varscan2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as rs775423572; called by mutect2, pindel, varscan2
- LHX4 | c.802G>A p.G268S | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs368040014; called by muse, mutect2, varscan2
- LIG4 | c.1949C>A p.T650N | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV63596409; called by muse, mutect2, varscan2
- LIPE | c.1751C>T p.T584M | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as rs774493314, COSV54921300; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | catalogued as rs780042765; called by mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 30/89 reads (34%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LONRF1 | c.1391A>T p.Y464F | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs753609881, COSV68035932; called by muse, mutect2, varscan2
- LPAR5 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs762905097, COSV61692036; called by muse, mutect2, varscan2
- LRATD1 | c.176dup p.C61Lfs*108 | Frame Shift Ins (INS) | VAF 16/32 reads (50%) | catalogued as rs756621869; called by mutect2, varscan2
- LRP12 | c.1523T>C p.L508P | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52625623; called by muse, mutect2, varscan2
- LRRC17 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs755652219, COSV50863993; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC2 | c.1054C>A p.L352I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV56124936; called by muse, mutect2, varscan2
- LRRC39 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV61582662; called by muse, mutect2, varscan2
- LRRC4 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.172); catalogued as COSV50813251; called by muse, varscan2
- LRRC8E | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 118/139 reads (85%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs923293235, COSV60716966; called by muse, mutect2, varscan2
- LRRCC1 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs551964362, COSV64482581; called by muse, mutect2
- LRRK1 | c.3019C>T p.R1007W | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs370459525; called by muse, mutect2, varscan2
- LRRK1 | c.3920A>C p.E1307A | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52601960; called by muse, mutect2, varscan2
- LRRK2 | c.4385G>A p.R1462H | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs142095251, COSV54147004; called by muse, mutect2, varscan2
- LRRTM4 | c.1277T>C p.I426T | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV69138998; called by muse, mutect2, varscan2
- LRTM1 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs779554165, COSV55513807; called by muse, mutect2, varscan2
- LTBP2 | c.3549G>T p.E1183D | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.509); catalogued as COSV56204854; called by muse, mutect2, varscan2
- LTBP4 | c.1995C>G p.H665Q (on ENST00000308370 / NM_001042544.1; = p.H628Q on NM_003573.2) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.192); catalogued as rs1052444573, COSV52576157; called by muse, mutect2, varscan2
- LTBP4 | c.4636G>A p.G1546S (on ENST00000308370 / NM_001042544.1; = p.G1509S on NM_003573.2) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1324797536, COSV52576178; called by muse, mutect2
- LUM | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs777345268, COSV57127390; called by muse, mutect2, varscan2
- LY75 | c.4613G>A p.R1538Q | Missense Mutation (SNP) | VAF 75/229 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749646788, COSV55101915; called by muse, mutect2, varscan2
- MACC1 | c.2051T>A p.I684N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV60540860; called by muse, mutect2, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as rs752439249; called by mutect2, varscan2
- MACROH2A2 | c.112A>G p.K38E | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); catalogued as COSV64712336; called by muse, mutect2, varscan2
- MADD | c.3281G>A p.R1094Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.043); catalogued as rs752053057, COSV60620389; called by muse, mutect2, varscan2
- MAGIX | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.221); catalogued as COSV66255700; called by muse, mutect2, varscan2
- MAML1 | c.2677A>G p.M893V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV52983001; called by muse, mutect2, varscan2
- MAN2B1 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs574049175, COSV55470075; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs1238467062, COSV61009717; called by muse, mutect2, varscan2
- MAP2K3 | c.719T>C p.L240P (on ENST00000342679 / NM_145109.3; = p.L211P on NM_002756.4) | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.917); catalogued as COSV100383386; called by muse, mutect2, varscan2
- MAP3K12 | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.211); catalogued as rs149876591; called by muse, mutect2
- MAP6 | c.2215G>T p.G739C | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.428); catalogued as COSV59074180; called by muse, mutect2
- MAPKAP1 | c.1414G>A p.A472T (on ENST00000265960 / NM_001006617.3; = p.A436T on NM_024117.3) | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.302); catalogued as rs759492877, COSV56364791; called by muse, mutect2, varscan2
- MARF1 | c.3058G>A p.G1020S | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60019899; called by muse, mutect2, varscan2
- MARK3 | c.1157A>G p.K386R | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as COSV53506278; called by muse, mutect2, varscan2
- MARS2 | c.970C>A p.L324M | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56570735; called by muse, mutect2, varscan2
- MARVELD3 | c.948del p.Y317Tfs*45 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs747980715, COSV51704302; called by mutect2, pindel, varscan2
- MAU2 | c.1114dup p.R372Pfs*61 | Frame Shift Ins (INS) | VAF 12/45 reads (27%) | catalogued as rs1226778907; called by mutect2, pindel, varscan2
- MAZ | c.39del p.F14Sfs*15 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs767720617; called by mutect2, varscan2
- MBD6 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs570363261, COSV63072969, COSV63076207; called by muse, mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 24/59 reads (41%) | catalogued as rs746267361; called by mutect2, varscan2
- MBD6 | c.2569C>T p.R857W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs773001370, COSV63072977; called by muse, mutect2, varscan2
- MBTPS1 | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1196439688, COSV58569334; called by muse, mutect2, varscan2
- MCF2L2 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61049209; called by muse, mutect2, varscan2
- MCTP2 | c.1283A>G p.H428R | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV59140748; called by muse, mutect2, varscan2
- MCUR1 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as rs145895773; called by muse, mutect2, varscan2
- MDH1B | c.1269G>T p.E423D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as COSV65588536; called by muse, mutect2, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 84/182 reads (46%) | catalogued as rs750092100; called by mutect2, varscan2
- MECP2 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs186663314, COSV57651793; called by muse, mutect2, varscan2
- MEIS1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as COSV55483474; called by muse, mutect2, varscan2
- MEIS1 | c.923T>C p.L308S | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV55483494; called by muse, mutect2, varscan2
- MEIS2 | c.754+2T>C p.X252_splice (on ENST00000561208 / NM_170675.5; = p.X239_splice on NM_002399.3) | Splice Site (SNP) | VAF 23/69 reads (33%) | catalogued as COSV54931450; called by muse, mutect2, varscan2
- MFSD6L | c.1602G>A p.W534* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV61687379; called by muse, mutect2, varscan2
- MIA2 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as rs1198250178, COSV54488632, COSV54498701; called by muse, mutect2, varscan2
- MIA2 | c.1562C>A p.P521H | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54488648; called by muse, mutect2, varscan2
- MIA3 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1384295636, COSV60509570; called by muse, mutect2, varscan2
- MICAL2 | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.267); catalogued as rs199894889, COSV56316453; called by muse, varscan2
- MICAL2 | c.1885G>A p.V629M | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs972563428, COSV56316484; called by muse, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MINAR1 | c.2647G>A p.E883K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.297); catalogued as rs750465556, COSV59580854; called by muse, mutect2, varscan2
- MIS18BP1 | c.865A>G p.S289G | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV60369051; called by muse, mutect2
- MKI67 | c.698del p.N233Mfs*12 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | catalogued as rs749903408; called by mutect2, varscan2
- MKNK1 | c.1239G>T p.E413D | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.098); catalogued as COSV57860460, COSV57860465; called by muse, mutect2, varscan2
- MKS1 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58302610; called by muse, mutect2, varscan2
- MMEL1 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as COSV56518408; called by muse, mutect2, varscan2
- MMP16 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs760308984, COSV54151216; called by muse, mutect2, varscan2
- MMP9 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs200637345, COSV63433749; called by muse, mutect2, varscan2
- MMP9 | c.1211G>A p.G404D | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63433752; called by muse, mutect2, varscan2
- MOB3C | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV54718136; called by muse, mutect2, varscan2
- MOK | c.313del p.I105Lfs*25 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as rs753079987; called by mutect2, varscan2
- MPHOSPH8 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 73/197 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV64054292; called by muse, mutect2, varscan2
- MPV17 | c.263_265del p.K88del | In Frame Del (DEL) | VAF 30/76 reads (39%) | catalogued as rs267607263; called by pindel, varscan2
- MPZL2 | c.442T>C p.F148L | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.047); catalogued as COSV54048358; called by muse, mutect2, varscan2
- MROH5 | c.3449C>T p.A1150V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.157); catalogued as rs753528694, COSV61471091; called by muse, mutect2, varscan2
- MRPS15 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776496972, COSV64152121; called by muse, mutect2, varscan2
- MS4A14 | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs376488191; called by muse, mutect2, varscan2
- MSH5 | c.783C>A p.C261* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as COSV65208688; called by muse, mutect2, varscan2
- MSRB3 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs542501613, COSV57587729; called by muse, mutect2, varscan2
- MTA3 | c.871A>G p.N291D | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV65922001; called by muse, mutect2, varscan2
- MTF1 | c.1279C>A p.L427I | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65988350; called by muse, mutect2, varscan2
- MTHFD1L | c.2684A>G p.Y895C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770387415, COSV66223722; called by muse, mutect2, varscan2
- MTMR7 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs968622478, COSV51663038; called by muse, mutect2, varscan2
- MTOR | c.1246A>G p.T416A | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV63868422; called by muse, mutect2, varscan2
- MTSS1 | c.1972A>G p.T658A | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV52674269; called by muse, mutect2, varscan2
- MUC1 | c.3275G>A p.G1092D (on ENST00000611571 / NM_001371720.1; = p.G103D on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.076); catalogued as COSV58111388; called by muse, mutect2, varscan2
- MUC2 | c.2467G>A p.V823I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs749304362; called by muse, mutect2, varscan2
- MUC2 | c.1003C>A p.P335T | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.63); catalogued as COSV61240017, COSV61244235; called by muse, mutect2
- MUC5B | c.1420_1422del p.N474del | In Frame Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs151023614; called by mutect2, pindel, varscan2
- MUCL3 | c.1433G>A p.R478H (on ENST00000304311; = p.R1354H on NM_080870.4) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.065); catalogued as rs769541066, COSV58515706; called by muse, mutect2, varscan2
- MX1 | c.1642_1644del p.K548del | In Frame Del (DEL) | VAF 72/202 reads (36%) | catalogued as rs1171035030; called by mutect2, pindel, varscan2
- MXD1 | c.335A>G p.D112G | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV52479092; called by muse, mutect2, varscan2
- MXRA5 | c.6427G>A p.A2143T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.421); catalogued as COSV54223900; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs764857791; called by mutect2, pindel
- MXRA8 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV58509838; called by muse, mutect2, varscan2
- MYC | c.269G>A p.G90D (on ENST00000377970; = p.G105D on NM_002467.6) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52367541; called by muse, mutect2, varscan2
- MYH10 | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 14/186 reads (8%) | catalogued as rs1390814552, COSV52595024; called by muse, mutect2
- MYH11 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770613752, COSV55541978; called by muse, mutect2, varscan2
- MYO10 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1027746803, COSV72453817, COSV72453865; called by muse, mutect2, varscan2
- MYO18A | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as rs751612877, COSV62862381; called by muse, mutect2, varscan2
- MYO18A | c.627del p.V210Wfs*86 | Frame Shift Del (DEL) | VAF 35/95 reads (37%) | catalogued as COSV62866672, COSV62872682; called by mutect2, pindel, varscan2
1,364 further variants in this file (877 protein-altering or splice-affecting, 452 silent, 35 other) are not listed here.
